Somatic mutation profile of tumor specimen MP2PRT-PAVHUK-TMP1-A (aliquot MP2PRT-PAVHUK-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVHUK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,180 days).
Specimen MP2PRT-PAVHUK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 057cff2e-a9be-4039-8989-af270685d2eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHUK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHUK-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90f03735-3b01-4edb-94fb-bdb5d6603154

The open-access MAF lists 32 somatic variants for this specimen: 20 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 11, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QA | c.238G>A p.G80S | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261736237, COSV99081036; called by muse, mutect2
- CTPS1 | c.1187dup p.L396Ffs*13 | Frame Shift Ins (INS) | VAF 26/225 reads (12%) | catalogued as rs36007898; called by mutect2, pindel, varscan2
- DHX8 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 53/428 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1283263382, COSV99292786; called by muse, mutect2, varscan2
- DNAH11 | c.6245G>A p.R2082Q | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs563280837, COSV60956774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH9 | c.1806G>C p.K602N | Missense Mutation (SNP) | VAF 68/344 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV52333525; called by muse, mutect2, varscan2
- GOLGA6L10 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 98/922 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs199757334; called by muse, varscan2
- HS1BP3 | c.784+1G>A p.X262_splice | Splice Site (SNP) | VAF 99/192 reads (52%) | catalogued as rs372865396; called by muse, mutect2, varscan2
- MFN2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 45/212 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1011639786, COSV52420534; called by muse, mutect2, varscan2
- PLA2G3 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 220/510 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs530887516, COSV53212447; called by muse, mutect2, varscan2
- SLC9A5 | c.1110C>A p.F370L | Missense Mutation (SNP) | VAF 58/301 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV55363440; called by muse, mutect2, varscan2
- TMEM86A | c.478C>T p.R160* | Nonsense Mutation (SNP) | VAF 193/496 reads (39%) | catalogued as rs370577203; called by muse, mutect2, varscan2
- ACD | c.1501C>T p.Q501* (on ENST00000620338; = p.Q412* on NM_022914.3) | Nonsense Mutation (SNP) | VAF 58/277 reads (21%) | called by muse, mutect2, varscan2
- ADAM2 | c.1323del p.E442Kfs*38 | Frame Shift Del (DEL) | VAF 119/328 reads (36%) | called by mutect2, pindel, varscan2
- C3orf38 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 13/285 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2
- KIAA0895L | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 69/299 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- LRRC53 | c.3475G>C p.D1159H | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2
- MAGT1 | c.802G>C p.E268Q (on ENST00000618282 / NM_001367916.1; = p.E300Q on NM_032121.5) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNAP91 | c.2592G>A p.M864I | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- SPTY2D1OS | c.18G>A p.W6* | Nonsense Mutation (SNP) | VAF 18/367 reads (5%) | called by muse, mutect2
- ZNF267 | c.2176_2177del p.N726Lfs*2 | Frame Shift Del (DEL) | VAF 94/282 reads (33%) | called by mutect2, pindel*, varscan2*
- CCDC92 | c.507C>G p.L169= | Silent (SNP) | VAF 68/904 reads (8%) | called by muse, mutect2
- CTCF | c.1476G>A p.E492= | Silent (SNP) | VAF 76/336 reads (23%) | called by muse, mutect2, varscan2
- GJA3 | c.1233C>G p.L411= | Silent (SNP) | VAF 176/724 reads (24%) | catalogued as COSV53834274; called by muse, mutect2, varscan2
- HNF4A | c.675C>T p.G225= | Silent (SNP) | VAF 33/394 reads (8%) | catalogued as rs751231466; called by muse, mutect2
- IL10RA | c.549G>A p.K183= | Silent (SNP) | VAF 54/211 reads (26%) | called by muse, mutect2, varscan2
- LGI1 | c.1575C>T p.F525= | Silent (SNP) | VAF 30/229 reads (13%) | called by muse, mutect2, varscan2
- PCDHGB3 | c.150C>G p.L50= | Silent (SNP) | VAF 12/452 reads (3%) | catalogued as COSV53925375; called by muse, mutect2
- RNF13 | c.63C>G p.V21= | Silent (SNP) | VAF 35/296 reads (12%) | called by muse, mutect2, varscan2
- SAGE1 | c.396A>G p.P132= | Silent (SNP) | VAF 113/155 reads (73%) | called by muse, mutect2, varscan2
- TRIM7 | c.30C>T p.P10= | Silent (SNP) | VAF 189/445 reads (42%) | called by muse, mutect2, varscan2
- TRPM6 | c.2628C>T p.S876= | Silent (SNP) | VAF 66/219 reads (30%) | catalogued as rs746415353; called by muse, mutect2, varscan2
- KLC2 | c.*328C>G | 3'UTR (SNP) | VAF 184/470 reads (39%) | called by muse, mutect2, varscan2
